CPTAC case C3L-09061 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ecd86bbc-cf55-4103-95c8-a84cc80386c4

Demographics
Sex at birth: female; Race: white; Year of birth: 1976; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 45.4 years (16,583 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: R2; Days to last known disease status: -6 days; Progression or recurrence: no; Days to last follow up: -6 days; Tumor focality: Unifocal.

Follow-up (1 entry)
- Follow-up contact recording only the day: day -6.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 7.5; Cigarettes per day: 15; Tobacco smoking onset year: 2011; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09061-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 158 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09061-25: Section location: Antrum; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3L-09061-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
